Gene-level copy-number profile of tumor specimen TCGA-S9-A6WM-01A from TCGA case TCGA-S9-A6WM, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 59.6 years (21,761 days).
Specimen TCGA-S9-A6WM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.d77c8890-affc-49b0-b582-6b90f5630f13.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-S9-A6WM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/214b4a39-be26-4a7f-ba42-052c189c73ea

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 2: 2,403; copy number 3: 5,237; copy number 4: 6,455; copy number 5: 26,759; copy number 6: 13,459; copy number 7: 2,411; copy number 8: 13; copy number 10: 2,999; copy number 31: 47; copy number 103: 11; copy number 141: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-S9-A6WM-01A-12D-A33S-01): tumor purity 0.88, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,982,881–8,344,167, 13 genes: Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr9:21,967,752–22,214,672, 8 genes (within-gene range 0–3): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 62 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,542,325–55,260,256, 15 genes, copy number 103–141: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr17:75,318,076–76,121,576, 47 genes, copy number 31: GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38, AC087289.3, FBF1, ACOX1, AC087289.4, TEN1-CDK3, TEN1, CDK3, EVPL, SRP68, ZACN, GALR2, EXOC7, AC018665.1, MIR6868.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
